Somatic mutation profile of tumor specimen HCM-BROD-0874-C43-06A (aliquot HCM-BROD-0874-C43-06A-11D-A85K-36) from HCMI case HCM-BROD-0874-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.5 years (21,744 days).
Specimen HCM-BROD-0874-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9180ab7d-6c19-4a32-8680-1a0fd399f5ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0874-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0874-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bbdeb40-47d4-4c61-9b95-e52381d7847c

The open-access MAF lists 2,229 somatic variants for this specimen: 1,422 protein-altering or splice-affecting, 708 silent, 99 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,302, Silent 708, Nonsense Mutation 73, Intron 55, Splice Region 25, 3'UTR 13, Frame Shift Del 10, RNA 9, 3'Flank 8, 5'Flank 7, 5'UTR 7, Splice Site 6.

Variants (750 of 2,229; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.7681C>T p.Q2561* | Nonsense Mutation (SNP) | VAF 59/260 reads (23%) | catalogued as rs80358994; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.3641G>A p.G1214E | Missense Mutation (SNP) | VAF 275/337 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886248, CM052217; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 282/319 reads (88%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 108/340 reads (32%) | catalogued as rs727504301, CM033658; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 50/290 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- RIT1 | c.268A>G p.M90V | Missense Mutation (SNP) | VAF 425/480 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557960039, CM167019, COSV64170951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 140/340 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 151/368 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAMP | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 176/280 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV50309213; called by muse, mutect2, varscan2
- ABCA13 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 154/255 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1436907195, COSV70033475; called by muse, mutect2, varscan2
- ABCA13 | c.11243G>A p.G3748E | Missense Mutation (SNP) | VAF 100/366 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV71285536; called by muse, mutect2, varscan2
- ABCA7 | c.5233C>T p.L1745F | Missense Mutation (SNP) | VAF 130/262 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as CD166825, COSV99566241; called by muse, mutect2, varscan2
- AC100868.1 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 116/296 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); catalogued as rs763542788; called by muse, mutect2, varscan2
- AC134980.2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs200194923, COSV100171580; called by mutect2, varscan2
- ACSS3 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs989417666, COSV54087157; called by muse, mutect2, varscan2
- ADAL | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 169/319 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs879198727; called by muse, mutect2, varscan2
- ADAM7 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.753); catalogued as COSV51541095; called by muse, mutect2, varscan2
- ADAMTS18 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 203/252 reads (81%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51424396; called by muse, mutect2, varscan2
- ADAMTS2 | c.2768G>A p.W923* | Nonsense Mutation (SNP) | VAF 189/430 reads (44%) | catalogued as rs1160288604; called by muse, mutect2, varscan2
- ADAMTS9 | c.5435A>T p.D1812V | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447073072; called by muse, mutect2, varscan2
- ADAR | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 495/543 reads (91%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.579); catalogued as rs1557888669; called by muse, mutect2, varscan2
- ADH1A | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 44/558 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52925726; called by muse, mutect2
- ADH1C | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs770280294; called by muse, mutect2
- AHNAK | c.11621C>T p.S3874F | Missense Mutation (SNP) | VAF 170/436 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1232565733; called by muse, mutect2, varscan2
- AHNAK | c.5801C>T p.P1934L | Missense Mutation (SNP) | VAF 243/534 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446311878; called by muse, mutect2, varscan2
- AL136295.1 | c.2309C>T p.S770F | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as rs752115104; called by muse, mutect2, varscan2
- ALAS2 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 166/191 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58189433; called by muse, mutect2, varscan2
- ALDH1L1 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 196/227 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs760924764; called by muse, mutect2, varscan2
- ALLC | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 84/430 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1183049932; called by muse, mutect2
- ALMS1 | c.5785C>T p.R1929W | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs938557636; called by muse, mutect2, varscan2
- ALPL | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 276/377 reads (73%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV100876209; called by muse, mutect2, varscan2
- ALS2CL | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 319/436 reads (73%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs200941139, COSV59673499; called by muse, varscan2
- AMY1B | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 201/264 reads (76%) | SIFT tolerated (0.34); PolyPhen benign (0.243); catalogued as COSV100375566; called by muse, mutect2, varscan2
- ANGEL1 | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 132/263 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs747200123, COSV51873786; called by muse, mutect2, varscan2
- ANGPT4 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 110/298 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1292675024; called by muse, mutect2, varscan2
- ANK2 | c.8798C>T p.S2933F | Missense Mutation (SNP) | VAF 344/406 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs771003489; called by muse, mutect2, varscan2
- ANKFN1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 148/224 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs765917235; called by muse, mutect2, varscan2
- ANKIB1 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs547575488; called by muse, varscan2
- ANKRD30A | c.3379G>A p.E1127K (on ENST00000611781; = p.E1071K on NM_052997.2) | Missense Mutation (SNP) | VAF 172/205 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV64616667; called by muse, mutect2, varscan2
- ANKRD30B | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 253/312 reads (81%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.801); catalogued as COSV62811725; called by muse, mutect2, varscan2
- ANKRD31 | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 132/320 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.129); catalogued as COSV57163868; called by muse, mutect2, varscan2
- ANO1 | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1319867351, COSV62444925; called by muse, mutect2, varscan2
- ANO3 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV56780653; called by muse, mutect2, varscan2
- AOX1 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 67/373 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as rs756119874, COSV101022164; called by muse, mutect2, varscan2
- AP5B1 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 223/483 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV57503055; called by muse, mutect2, varscan2
- APBA1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 412/467 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1564062638, COSV55228003; called by muse, mutect2, varscan2
- APOB | c.12931G>A p.E4311K | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as COSV99265878; called by muse, mutect2, varscan2
- APOL4 | c.301G>A p.E101K (on ENST00000352371 / NM_145660.2; = p.E98K on NM_030643.4) | Missense Mutation (SNP) | VAF 315/462 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1475801583, COSV60654312; called by muse, varscan2
- APOL5 | c.141C>T p.F47= | Splice Region (SNP) | VAF 369/541 reads (68%) | catalogued as rs757956930; called by muse, mutect2, varscan2
- ARHGAP36 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 176/214 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV52265695; called by muse, mutect2, varscan2
- ARHGEF15 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 109/244 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs766671999; called by muse, mutect2, varscan2
- ARHGEF15 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 158/386 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201103318; called by muse, mutect2, varscan2
- ARHGEF5 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 176/961 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as COSV50218152, COSV99283276; called by muse, varscan2
- ARHGEF6 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs755130149; called by muse, varscan2
- ARHGEF6 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 206/257 reads (80%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.218); catalogued as COSV51687879, COSV51690842; called by muse, varscan2
- ARID4B | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 319/350 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1212395172; called by muse, mutect2, varscan2
- ARL6IP4 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 389/454 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); catalogued as rs1476805993; called by muse, mutect2, varscan2
- ARPP21 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs149733002; called by muse, mutect2, varscan2
- ASIC4 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1260516411; called by muse, mutect2, varscan2
- ASPHD2 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 141/657 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53218770; called by muse, mutect2, varscan2
- ASPM | c.9493C>T p.H3165Y | Missense Mutation (SNP) | VAF 397/422 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV99660147, COSV99661094; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 335/372 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ATAD3A | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 236/355 reads (66%) | catalogued as rs774681303; called by muse, mutect2, varscan2
- ATN1 | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 208/263 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); catalogued as rs1555144090; called by muse, mutect2, varscan2
- ATP12A | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 352/465 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566077545, COSV54515540; called by muse, mutect2, varscan2
- ATP8A1 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV52548882; called by muse, mutect2
- ATP8B1 | c.3040C>T p.R1014* | Nonsense Mutation (SNP) | VAF 162/213 reads (76%) | catalogued as rs781213892, CM043831, COSV52178820; called by muse, mutect2, varscan2
- BARX2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 105/138 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456206651, COSV55652434; called by muse, mutect2, varscan2
- BFSP1 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 206/595 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.096); catalogued as rs755461021, COSV64901289; called by muse, mutect2
- BIRC3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 170/216 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs147996132; called by muse, mutect2, varscan2
- BIRC6 | c.3652C>T p.R1218C | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs776885767, COSV70205181; called by muse, mutect2, varscan2
- BMP5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 358/742 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63702572; called by muse, varscan2
- BRINP3 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 500/543 reads (92%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1399315630, COSV66519115; called by muse, mutect2, varscan2
- C17orf64 | c.643T>C p.S215P | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756797485, COSV52258288; called by muse, mutect2, varscan2
- C1QTNF2 | c.137T>A p.M46K (on ENST00000393975; = p.M1? on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/295 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67432832; called by muse, mutect2, varscan2
- C2orf16 | c.5426C>T p.P1809L | Missense Mutation (SNP) | VAF 376/592 reads (64%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV62676386; called by muse, mutect2, varscan2
- C3 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 178/327 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766179097; called by muse, mutect2, varscan2
- C6 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 109/268 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs867408360, COSV54706337; called by muse, mutect2, varscan2
- C7 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 107/262 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV57471178; called by muse, mutect2, varscan2
- C7 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 112/234 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1561262611; called by muse, mutect2, varscan2
- C7 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 125/284 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57470310, COSV57477578; called by muse, mutect2, varscan2
- CABIN1 | c.3077T>C p.L1026P | Missense Mutation (SNP) | VAF 362/546 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1405231047, COSV54078995; called by muse, mutect2, varscan2
- CACNA1F | c.5908G>A p.E1970K | Missense Mutation (SNP) | VAF 188/248 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs371796154, COSV54294411, COSV99603155; called by muse, mutect2, varscan2
- CACNA1G | c.3249G>A p.M1083I | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs777415638, COSV61724421; called by muse, mutect2, varscan2
- CACNA1H | c.6239C>T p.S2080F | Missense Mutation (SNP) | VAF 494/569 reads (87%) | SIFT tolerated (0.2); PolyPhen benign (0.204); catalogued as COSV52356109; called by muse, mutect2, varscan2
- CACNA2D1 | c.2248G>A p.E750K (on ENST00000356253 / NM_001366867.1; = p.E738K on NM_000722.4) | Missense Mutation (SNP) | VAF 168/224 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV62397243; called by muse, mutect2, varscan2
- CACNG2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 112/442 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100268446; called by muse, mutect2, varscan2
- CADPS | c.3555C>T p.F1185= | Splice Region (SNP) | VAF 59/173 reads (34%) | catalogued as rs770554516, COSV51894992; called by muse, mutect2, varscan2
- CADPS | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV51883185; called by muse, mutect2, varscan2
- CAGE1 | c.1279G>A p.E427K (on ENST00000512086; = p.E291K on NM_205864.3) | Missense Mutation (SNP) | VAF 211/549 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1465298705; called by muse, mutect2, varscan2
- CALHM1 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 237/303 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100324349; called by muse, mutect2, varscan2
- CATSPERB | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 207/379 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as rs1215491838, COSV56426370; called by muse, mutect2, varscan2
- CATSPERB | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 118/251 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99830647; called by muse, mutect2, varscan2
- CCDC142 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 318/502 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51779697; called by muse, varscan2
- CCDC168 | c.14791G>A p.E4931K | Missense Mutation (SNP) | VAF 165/295 reads (56%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs1439993263; called by muse, mutect2, varscan2
- CCDC182 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 269/417 reads (65%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.384); catalogued as rs750904613; called by muse, mutect2, varscan2
- CCDC73 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58795949; called by muse, mutect2, varscan2
- CCSER1 | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 16/288 reads (6%) | catalogued as COSV100388731; called by muse, mutect2
- CD163L1 | c.1928G>A p.G643E | Missense Mutation (SNP) | VAF 224/282 reads (79%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV58011409; called by muse, mutect2, varscan2
- CD207 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 259/408 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101338585; called by muse, mutect2, varscan2
- CD33 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 77/348 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV51800032; called by muse, mutect2, varscan2
- CD96 | c.947G>A p.G316E (on ENST00000283285 / NM_198196.3; = p.G300E on NM_005816.5) | Missense Mutation (SNP) | VAF 103/121 reads (85%) | SIFT tolerated (0.79); PolyPhen benign (0.028); catalogued as COSV51916437; called by muse, varscan2
- CDH9 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV50370647, COSV50459979; called by muse, mutect2, varscan2
- CDHR5 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752124353; called by muse, mutect2
- CDK12 | c.4372C>T p.H1458Y (on ENST00000447079 / NM_016507.4; = p.H1449Y on NM_015083.3) | Missense Mutation (SNP) | VAF 94/487 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV71001445; called by muse, mutect2, varscan2
- CDK8 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs756268970, COSV67423737; called by muse, varscan2
- CDKN2A | c.300del p.A102Rfs*44 | Frame Shift Del (DEL) | VAF 582/1053 reads (55%) | catalogued as COSV58691635; called by pindel, varscan2
- CDYL2 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 224/288 reads (78%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as COSV73654957; called by muse, mutect2, varscan2
- CEACAM4 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 215/381 reads (56%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); catalogued as COSV99701031; called by muse, mutect2, varscan2
- CEACAM7 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99137365; called by muse, mutect2, varscan2
- CECR2 | c.671C>T p.S224F (on ENST00000342247 / NM_001290047.2; = p.S61F on NM_001290046.1) | Missense Mutation (SNP) | VAF 300/480 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as COSV52849627; called by muse, mutect2, varscan2
- CELF6 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs769547615, COSV54715476; called by muse, mutect2, varscan2
- CFAP20DC | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 318/464 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1377040246; called by muse, mutect2, varscan2
- CFAP221 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 217/308 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV99732367; called by muse, mutect2, varscan2
- CFAP47 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 166/200 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52884843, COSV52891359; called by muse, mutect2, varscan2
- CFAP47 | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 212/266 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV52881110; called by muse, mutect2, varscan2
- CFAP54 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 76/96 reads (79%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs879737066; called by muse, mutect2
- CFAP74 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 277/397 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54566104; called by muse, mutect2, varscan2
- CFAP99 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 43/558 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs778653308; called by muse, mutect2
- CFHR5 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 427/457 reads (93%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs890060392, COSV56819542; called by muse, mutect2, varscan2
- CFTR | c.173A>C p.D58A | Missense Mutation (SNP) | VAF 194/269 reads (72%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.902); catalogued as CM003234; called by muse, mutect2, varscan2
- CFTR | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 200/303 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs144720913, CM067769, COSV50060609, COSV50129630; called by muse, mutect2, varscan2
- CHD2 | c.2125C>T p.L709F | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67712320; called by muse, mutect2, varscan2
- CHRNA6 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 129/342 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775552140, COSV99373299; called by muse, mutect2, varscan2
- CLCN1 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 178/385 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV58368220; called by muse, mutect2, varscan2
- CLEC5A | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 211/380 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV101407799; called by muse, mutect2, varscan2
- CLVS1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 143/306 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as COSV100370801; called by muse, mutect2, varscan2
- CLVS2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 179/209 reads (86%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.605); catalogued as COSV51562421; called by muse, mutect2, varscan2
- CMYA5 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 172/391 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as COSV71410348; called by muse, mutect2, varscan2
- CNGA1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 39/404 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs769046389, COSV62055358; called by muse, mutect2
- CNGA3 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 203/290 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs749949335; called by muse, mutect2, varscan2
- CNTNAP2 | c.1715C>T p.T572I | Missense Mutation (SNP) | VAF 213/448 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100668586; called by muse, mutect2, varscan2
- CNTNAP2 | c.3384C>T p.L1128= | Splice Region (SNP) | VAF 146/454 reads (32%) | catalogued as rs992898313; called by muse, mutect2, varscan2
- COL11A2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 394/1071 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs764076227, COSV100554553; called by muse, mutect2, varscan2
- COL14A1 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 136/321 reads (42%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.995); catalogued as rs1317268989, COSV52858084; called by muse, mutect2, varscan2
- COL14A1 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1316632101; called by muse, mutect2, varscan2
- COL1A2 | c.3281C>T p.P1094L | Missense Mutation (SNP) | VAF 204/296 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV51964923; called by muse, mutect2, varscan2
- COL21A1 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 258/583 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs771765654, COSV55156257; called by muse, mutect2, varscan2
- COL21A1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 485/892 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1009121320, COSV55158368; called by muse, mutect2, varscan2
- COL4A2 | c.4358G>A p.G1453E | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64634165; called by muse, mutect2, varscan2
- COL4A3 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67416146; called by muse, mutect2, varscan2
- COL4A4 | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 154/249 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM014563; called by muse, mutect2, varscan2
- COL5A2 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 194/282 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768322852, COSV66411238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 148/175 reads (85%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV55201496; called by muse, mutect2, varscan2
- COL8A1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 226/372 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99658683; called by muse, mutect2, varscan2
- CPA4 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55984132, COSV55985226; called by muse, mutect2
- CPA4 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 54/572 reads (9%) | catalogued as rs774692846; called by muse, mutect2
- CPHXL | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 238/280 reads (85%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1215439491; called by muse, mutect2, varscan2
- CPNE3 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52207655; called by muse, mutect2, varscan2
- CPXM2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 120/158 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944271451, COSV53860832; called by muse, mutect2, varscan2
- CRYBG1 | c.3406C>T p.P1136S | Missense Mutation (SNP) | VAF 201/244 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64813921; called by muse, mutect2, varscan2
- CSF2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 109/278 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs747150863; called by muse, mutect2, varscan2
- CSMD1 | c.8668G>A p.E2890K (on ENST00000520002; = p.E2889K on NM_033225.6) | Missense Mutation (SNP) | VAF 134/272 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs199571932, COSV59300242, COSV99064756; called by muse, mutect2, varscan2
- CSMD2 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 91/501 reads (18%) | catalogued as rs867259644, COSV53934021; called by muse, mutect2, varscan2
- CSMD3 | c.10390C>T p.P3464S (on ENST00000297405 / NM_001363185.1; = p.P3295S on NM_052900.3) | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141126792, COSV52122184; called by muse, mutect2, varscan2
- CSMD3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.967); catalogued as rs536561292, COSV52113015; called by muse, mutect2, varscan2
- CTNNA2 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 185/313 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV58155619; called by muse, mutect2, varscan2
- CTNND2 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 143/323 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.03); catalogued as COSV58889602; called by muse, mutect2, varscan2
- CXorf58 | c.857G>C p.R286P | Missense Mutation (SNP) | VAF 211/254 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64858744; called by muse, mutect2, varscan2
- CYP11A1 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779269933, COSV51432107; called by muse, mutect2, varscan2
- CYP2C19 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 172/214 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs867860347, COSV64908478, COSV64909232; called by muse, mutect2, varscan2
- CYP2D6 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 226/1674 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs748519122; called by muse, varscan2
- CYP2W1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 107/384 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as rs1441933750; called by muse, mutect2, varscan2
- CYP4A22 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 397/584 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1485938745, COSV53741605; called by muse, mutect2, varscan2
- CYP4F3 | c.1397G>A p.R466K | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs894963953, COSV55408197; called by muse, mutect2, varscan2
- CYTH4 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 286/448 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs868185751, COSV50634225; called by muse, mutect2, varscan2
- DAPP1 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 270/344 reads (78%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.011); catalogued as COSV56453702; called by muse, mutect2, varscan2
- DBF4B | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 97/535 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs142562446, COSV59260243; called by muse, mutect2, varscan2
- DCAF17 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 205/318 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1223919095; called by muse, mutect2, varscan2
- DCLK1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 100/434 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV55171740; called by muse, mutect2, varscan2
- DCLRE1B | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 396/545 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs747277233; called by muse, mutect2, varscan2
- DEFB105A | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 74/484 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV58294716; called by muse, varscan2
- DEFB115 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 196/377 reads (52%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV68723046; called by muse, mutect2, varscan2
- DENND2C | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 61/490 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.166); catalogued as rs887055482; called by muse, mutect2, varscan2
- DHX16 | c.1183G>T p.V395F | Missense Mutation (SNP) | VAF 586/1105 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV64565886; called by muse, mutect2, varscan2
- DLEC1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 178/262 reads (68%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV57307670; called by muse, mutect2, varscan2
- DLG2 | c.2131C>T p.H711Y | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV104381757; called by muse, mutect2, varscan2
- DNAH5 | c.13487G>A p.R4496Q | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs759999227, COSV99454092; called by muse, mutect2, varscan2
- DNAJB7 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 462/692 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99344320; called by muse, mutect2, varscan2
- DOCK10 | c.2131A>G p.K711E | Missense Mutation (SNP) | VAF 233/368 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as rs1268565057; called by muse, mutect2, varscan2
- DOCK3 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 82/464 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs773945459; called by muse, mutect2, varscan2
- DOCK6 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 158/370 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.04); catalogued as rs745904472; called by muse, mutect2, varscan2
- DPYD | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 380/527 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64594494; called by muse, mutect2, varscan2
- DRAXIN | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 381/509 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99610545; called by muse, mutect2, varscan2
- DSC3 | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 157/190 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV64573151; called by muse, varscan2
- DSCAM | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 103/124 reads (83%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV68031123; called by muse, mutect2, varscan2
- DSCAM | c.2787G>A p.W929* | Nonsense Mutation (SNP) | VAF 99/120 reads (83%) | catalogued as COSV68032759; called by muse, mutect2, varscan2
- DSG1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 203/264 reads (77%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs770916767, COSV57134860; called by muse, mutect2, varscan2
- DSG1 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 247/298 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57133213; called by muse, varscan2
- DSG1 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 264/314 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs749203049; called by muse, varscan2
- DSG1 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 213/247 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs778003137, COSV57134002; called by muse, mutect2, varscan2
- DSP | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 140/414 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); catalogued as COSV65790764; called by muse, mutect2, varscan2
- DST | c.13363G>A p.V4455I (on ENST00000361203 / NM_001374722.1; = p.V2043I on NM_015548.5) | Missense Mutation (SNP) | VAF 206/462 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV55038669; called by muse, mutect2, varscan2
- DVL1 | c.2008C>T p.P670S (on ENST00000378888 / NM_001330311.2; = p.P645S on NM_004421.3) | Missense Mutation (SNP) | VAF 127/735 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs779009859; called by muse, mutect2, varscan2
- EBF2 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.199); catalogued as rs769738444, COSV101282191; called by muse, mutect2, varscan2
- EHMT1 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 308/364 reads (85%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs532880924, COSV58373626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF2AK4 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 176/334 reads (53%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.995); catalogued as COSV55465653; called by muse, mutect2, varscan2
- EIF4A3 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs753145766; called by muse, mutect2, varscan2
- EIF4G1 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 302/344 reads (88%) | SIFT tolerated (0.24); PolyPhen benign (0.186); catalogued as rs1300223766; called by muse, mutect2, varscan2
- ELF2 | c.367C>T p.P123S (on ENST00000379550 / NM_001331036.2; = p.P63S on NM_006874.4) | Missense Mutation (SNP) | VAF 215/260 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs772288725; called by muse, mutect2, varscan2
- ELF5 | c.731G>A p.R244Q (on ENST00000312319 / NM_198381.2; = p.R234Q on NM_001422.4) | Missense Mutation (SNP) | VAF 121/250 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs143099997; called by muse, mutect2, varscan2
- EPHA3 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 295/414 reads (71%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV60709250, COSV60725648; called by muse, mutect2, varscan2
- EPHA3 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV60725866; called by muse, mutect2, varscan2
- EPHA8 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 403/578 reads (70%) | catalogued as rs1272570562, COSV51263859; called by muse, mutect2, varscan2
- ERBB3 | c.3100C>T p.P1034S | Missense Mutation (SNP) | VAF 249/312 reads (80%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs748965595; called by muse, mutect2, varscan2
- ERC2 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 107/604 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99885862; called by muse, mutect2, varscan2
- ERICH3 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 482/670 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV100444943; called by muse, mutect2
- ERVMER34-1 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 37/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1162419277; called by muse, mutect2
- ESPNL | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 176/201 reads (88%) | catalogued as COSV54544546; called by muse, mutect2, varscan2
- EVX1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 184/641 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.119); catalogued as rs776053650; called by muse, mutect2, varscan2
- FAM120C | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 208/248 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV60258709; called by muse, mutect2, varscan2
- FAM124B | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as rs972144765; called by muse, mutect2, varscan2
- FAM170A | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 152/339 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV58924267; called by muse, mutect2, varscan2
- FAM180A | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 44/702 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1412266948; called by muse, mutect2
- FAM83B | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 307/729 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60920165; called by muse, mutect2, varscan2
- FAM83B | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 303/752 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV60922315; called by muse, mutect2, varscan2
- FAM83B | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 217/553 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs766774691, COSV60919265; called by muse, mutect2, varscan2
- FANCD2 | c.3527A>G p.N1176S | Missense Mutation (SNP) | VAF 290/410 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764205355; called by muse, mutect2, varscan2
- FAT3 | c.8939G>A p.S2980N | Missense Mutation (SNP) | VAF 161/355 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53177923; called by muse, mutect2, varscan2
- FAT4 | c.11389G>A p.G3797R | Missense Mutation (SNP) | VAF 318/417 reads (76%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1218915760, COSV100626803, COSV58673045, COSV58704036; called by muse, mutect2, varscan2
- FBLN2 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 85/482 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV55485739; called by muse, mutect2, varscan2
- FBN1 | c.1959T>A p.V653= | Splice Region (SNP) | VAF 45/196 reads (23%) | catalogued as rs1259303204; called by muse, mutect2, varscan2
- FBN3 | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 126/254 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs749453532, COSV54455724; called by muse, mutect2
- FBN3 | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 113/221 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as rs147529451; called by muse, mutect2, varscan2
- FBXO42 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 93/604 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs748281060, COSV65046929; called by muse, mutect2, varscan2
- FCGR1A | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 331/415 reads (80%) | SIFT tolerated (0.05); PolyPhen benign (0.184); catalogued as rs781880153; called by muse, mutect2, varscan2
- FCN1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 326/366 reads (89%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV65662719; called by muse, mutect2, varscan2
- FCN3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 333/482 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54640803; called by muse, mutect2, varscan2
- FCRL5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 625/681 reads (92%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs763929627, COSV62513493; called by muse, mutect2, varscan2
- FFAR4 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 252/327 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141464588; called by muse, mutect2, varscan2
- FLG | c.11267A>C p.D3756A | Missense Mutation (SNP) | VAF 770/854 reads (90%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.472); catalogued as COSV64245288; called by muse, mutect2, varscan2
- FLG2 | c.4010C>T p.S1337F | Missense Mutation (SNP) | VAF 537/632 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs746819915, COSV66166799; called by muse, mutect2, varscan2
- FLT1 | c.2159G>A p.R720K | Missense Mutation (SNP) | VAF 171/293 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56734332; called by muse, mutect2, varscan2
- FMN2 | c.3793C>T p.P1265S | Missense Mutation (SNP) | VAF 542/593 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142687; called by muse, mutect2, varscan2
- FOXA1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 166/606 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV51648233; called by muse, mutect2
- FOXA3 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100141509; called by muse, mutect2, varscan2
- FOXN1 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752558563; called by muse, mutect2, varscan2
- FOXR1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 154/199 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV57653553; called by muse, mutect2, varscan2
- FRAS1 | c.8182G>A p.G2728S | Missense Mutation (SNP) | VAF 319/417 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs915414147, COSV99347117; called by muse, mutect2, varscan2
- FRAS1 | c.9040C>T p.L3014F | Missense Mutation (SNP) | VAF 311/394 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV53623835; called by muse, mutect2, varscan2
- FREM3 | c.6064G>A p.V2022I | Missense Mutation (SNP) | VAF 28/417 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.547); catalogued as rs755201820; called by muse, mutect2
- FREM3 | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 56/550 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61680460; called by muse, mutect2
- FSD2 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 155/279 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58008746; called by muse, mutect2, varscan2
- FSTL5 | c.959C>G p.T320S | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV60229680; called by muse, mutect2, varscan2
- FTCD | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 239/295 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201753824, COSV52426509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRB2 | c.1499C>T p.S500F (on ENST00000274547; = p.S462F on NM_000813.3) | Missense Mutation (SNP) | VAF 111/323 reads (34%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.995); catalogued as COSV50903913; called by muse, mutect2, varscan2
- GABRB3 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1220761805, COSV54661057; called by muse, mutect2, varscan2
- GADL1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 84/420 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766744682, COSV56978852, COSV56978895; called by muse, varscan2
- GALC | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV54323724; called by muse, mutect2, varscan2
- GBA3 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 38/411 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as rs1369441971, COSV72438254, COSV72438766; called by muse, mutect2
- GCAT | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 268/402 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780863430; called by muse, mutect2, varscan2
- GIMAP8 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 300/580 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV56231157; called by muse, mutect2, varscan2
- GK2 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 279/378 reads (74%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV62628049; called by muse, mutect2, varscan2
- GLB1L3 | c.1832G>A p.W611* | Nonsense Mutation (SNP) | VAF 96/127 reads (76%) | catalogued as COSV101345138; called by muse, mutect2, varscan2
- GLT6D1 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 381/445 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1158461483; called by muse, mutect2, varscan2
- GPHN | c.1690C>T p.R564C (on ENST00000315266 / NM_001377519.1; = p.R597C on NM_020806.5) | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs1360125120, COSV104400759; called by muse, varscan2
- GPR158 | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 245/287 reads (85%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1374104989, COSV66264976, COSV66273219; called by muse, mutect2, varscan2
- GPR65 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 140/302 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.132); catalogued as rs558039201; called by muse, mutect2, varscan2
- GPRIN2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 597/1066 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV65402916; called by muse, mutect2, varscan2
- GPRIN2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 120/657 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as rs782738328, COSV65401181; called by muse, mutect2, varscan2
- GRHL2 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 108/245 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs766515922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIA1 | c.2597G>A p.G866E | Missense Mutation (SNP) | VAF 188/404 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.138); catalogued as rs1340594187; called by muse, mutect2, varscan2
- GRM6 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1185965317; called by muse, mutect2, varscan2
- GRXCR2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 190/433 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs447402, COSV65060697; called by muse, mutect2, varscan2
- GSAP | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 237/341 reads (70%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs370849463; called by muse, mutect2, varscan2
- GTPBP10 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1013329253; called by muse, mutect2, varscan2
- GYS2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 205/250 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs376712209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H6PD | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 85/448 reads (19%) | catalogued as rs1438111258; called by muse, mutect2, varscan2
- HCN1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 234/528 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57514706; called by muse, varscan2
- HDC | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 109/186 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as rs749851294, COSV51068330; called by muse, mutect2, varscan2
- HDC | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 141/261 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367618872, COSV51070116; called by muse, mutect2, varscan2
- HEATR4 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 115/384 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866192463; called by muse, mutect2, varscan2
- HEPACAM2 | c.587C>T p.S196F (on ENST00000394468 / NM_001039372.4; = p.S184F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/514 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.582); catalogued as COSV59063373; called by muse, mutect2, varscan2
- HEPHL1 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 167/401 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.506); catalogued as COSV100244227; called by muse, mutect2, varscan2
- HMCN1 | c.14362C>T p.P4788S | Missense Mutation (SNP) | VAF 566/641 reads (88%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV54899297; called by muse, mutect2, varscan2
- HMCN1 | c.14963T>C p.I4988T | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs1230866760, COSV54877830; called by muse, mutect2, varscan2
- HNRNPCL1 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 282/413 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.342); catalogued as rs1455984178; called by muse, mutect2, varscan2
- HOMEZ | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs200890395; called by muse, mutect2, varscan2
- HOXB8 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 287/499 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs749106433; called by muse, mutect2, varscan2
- HPSE | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 420/532 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183947666; called by muse, varscan2
- HRAS | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54238391, COSV54244417; called by muse, mutect2, varscan2
- HSD11B1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 538/609 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54829522; called by muse, mutect2, varscan2
- HSF5 | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 235/381 reads (62%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.005); catalogued as rs1450375404; called by muse, mutect2, varscan2
- HTR1E | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 277/348 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552106885; called by muse, mutect2, varscan2
- HYDIN | c.12454G>A p.D4152N | Missense Mutation (SNP) | VAF 114/144 reads (79%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as COSV66636846, COSV66638877; called by muse, mutect2, varscan2
- HYDIN | c.7063G>A p.E2355K | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV59253270; called by mutect2, varscan2
- IDO2 | c.791C>T p.S264F (on ENST00000389060; = p.S277F on NM_194294.2) | Missense Mutation (SNP) | VAF 155/401 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1034537903; called by muse, mutect2, varscan2
- IFI44L | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 93/507 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV60726789; called by muse, mutect2, varscan2
- IGF1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 198/247 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV61031622, COSV61033552; called by muse, mutect2, varscan2
- IGHA1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 167/554 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs1286596126; called by muse, mutect2, varscan2
- IGHV3-48 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as rs781906099; called by muse, mutect2, varscan2
- IGLON5 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1360349755; called by muse, mutect2, varscan2
- IHH | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 117/478 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV55393786; called by muse, varscan2
- IL1RAPL1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 209/248 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199864130, COSV56250433; called by muse, mutect2, varscan2
- IL1RL1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 231/377 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs150294315; called by muse, mutect2
- IL31 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 240/286 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756327888, COSV65476689; called by muse, mutect2, varscan2
- IL36B | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV52086453; called by muse, mutect2, varscan2
- IMPDH1 | c.542G>A p.R181K (on ENST00000470772 / NM_001142573.2; = p.R267K on NM_000883.4) | Missense Mutation (SNP) | VAF 131/414 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.297); catalogued as rs1483780664; called by muse, mutect2, varscan2
- IMPG2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 80/379 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs979308789, COSV51983494; called by muse, mutect2, varscan2
- INTS6L | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 131/167 reads (78%) | catalogued as COSV66085998; called by muse, mutect2, varscan2
- IQSEC3 | c.1157C>T p.S386F (on ENST00000538872 / NM_001170738.2; = p.S83F on NM_015232.1) | Missense Mutation (SNP) | VAF 205/259 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1221691608, COSV100407780, COSV58288922; called by muse, mutect2, varscan2
- IQUB | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs1021829808, COSV100227095; called by muse, mutect2, varscan2
- IRF5 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 157/340 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as COSV50859233; called by muse, mutect2, varscan2
- IRS2 | c.2929G>A p.D977N | Missense Mutation (SNP) | VAF 137/572 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs751311445; called by muse, mutect2, varscan2
- ITFG1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 302/351 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as rs527980093; called by muse, mutect2, varscan2
- ITPR1 | c.2263G>A p.E755K (on ENST00000354582; = p.E740K on NM_002222.7) | Missense Mutation (SNP) | VAF 109/543 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV56996351; called by muse, mutect2, varscan2
- ITPR1 | c.6861G>A p.M2287I (on ENST00000354582; = p.M2232I on NM_002222.7) | Missense Mutation (SNP) | VAF 77/408 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56988970; called by muse, mutect2, varscan2
- IVL | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 650/714 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs1410895544; called by muse, mutect2, varscan2
- IWS1 | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99767140; called by muse, mutect2, varscan2
- KANK4 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 386/431 reads (90%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1485212258, COSV62985916; called by muse, mutect2, varscan2
- KAT2A | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV56789548; called by muse, mutect2, varscan2
- KATNBL1 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.13); catalogued as COSV56623134, COSV56626046; called by muse, mutect2, varscan2
- KBTBD7 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 86/365 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as rs140042626; called by muse, mutect2, varscan2
- KCNB2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 163/358 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs866484467, COSV73051743; called by muse, mutect2, varscan2
- KCNB2 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 154/319 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as COSV73050743; called by mutect2, varscan2
- KCND2 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 56/433 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58582688; called by muse, mutect2, varscan2
- KCNK1 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 657/726 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64036358; called by muse, mutect2, varscan2
- KCNN1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 225/525 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as COSV55838443; called by muse, mutect2, varscan2
- KCP | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 138/431 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.375); catalogued as rs551314841; called by muse, mutect2, varscan2
- KCTD8 | c.1200G>A p.W400* | Nonsense Mutation (SNP) | VAF 50/482 reads (10%) | catalogued as COSV63593626; called by muse, mutect2, varscan2
- KDM1A | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 162/256 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327361293; called by muse, mutect2, varscan2
- KEL | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 41/652 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1215806158; called by muse, mutect2
- KHSRP | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 210/385 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV67919459; called by muse, mutect2, varscan2
- KIAA1210 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 177/213 reads (83%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs775653483, COSV68175814; called by muse, mutect2, varscan2
- KIAA1671 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 165/638 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV104422068; called by muse, mutect2, varscan2
- KIF16B | c.1782C>T p.P594= | Splice Region (SNP) | VAF 170/309 reads (55%) | catalogued as rs780867035; called by muse, mutect2, varscan2
- KIF1C | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 125/314 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs555256113, COSV57905880; called by muse, mutect2, varscan2
- KIF1C | c.3164C>T p.P1055L | Missense Mutation (SNP) | VAF 243/616 reads (39%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.122); catalogued as rs763684173; called by muse, mutect2, varscan2
- KIF2B | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 254/397 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1479558414, COSV52127285; called by muse, mutect2, varscan2
- KIR2DL1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 71/122 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs1392775546; called by muse, mutect2, varscan2
- KIR2DS4 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs530424690; called by muse, mutect2, varscan2
- KIRREL1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 438/475 reads (92%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs1296999444, COSV63292457; called by muse, varscan2
- KLC4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 401/719 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs756928667, COSV52434917; called by muse, mutect2, varscan2
- KLF8 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 328/406 reads (81%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100808452; called by muse, mutect2, varscan2
- KLHL1 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 128/243 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99060882; called by muse, mutect2, varscan2
- KLHL34 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 260/319 reads (82%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs148422098; called by muse, mutect2, varscan2
- KLKB1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs1285035172, COSV52994080; called by muse, mutect2
- KMT2A | c.6310G>T p.E2104* | Nonsense Mutation (SNP) | VAF 123/152 reads (81%) | catalogued as COSV100630037; called by muse, mutect2, varscan2
- KMT2B | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55867018; called by muse, mutect2, varscan2
- KMT2B | c.5743C>T p.R1915C | Missense Mutation (SNP) | VAF 328/583 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1471456268; called by muse, mutect2, varscan2
- KRT10 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 485/764 reads (63%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.989); catalogued as rs774951544; called by muse, mutect2, varscan2
- KRT33B | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 157/680 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1210131504; called by muse, mutect2, varscan2
- LAMA2 | c.7811G>A p.R2604Q | Missense Mutation (SNP) | VAF 180/211 reads (85%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs200853002, COSV104436759; called by muse, mutect2, varscan2
- LAMA5 | c.3736C>T p.L1246F | Missense Mutation (SNP) | VAF 216/607 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1201553411; called by muse, mutect2, varscan2
- LARP1B | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 215/284 reads (76%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs759640074, COSV99218598; called by muse, mutect2, varscan2
- LATS2 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 112/802 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV66878807; called by muse, varscan2
- LCOR | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 154/196 reads (79%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1371587683; called by muse, mutect2, varscan2
- LCOR | c.3634C>T p.P1212S | Missense Mutation (SNP) | VAF 133/177 reads (75%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.897); catalogued as rs1239242490; called by muse, mutect2, varscan2
- LFNG | c.1123C>T p.R375C (on ENST00000222725 / NM_001040167.2; = p.R246C on NM_002304.2) | Missense Mutation (SNP) | VAF 82/430 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs746683505, COSV56069552; called by muse, mutect2, varscan2
- LIFR | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 175/367 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs746053471, COSV54686247; called by muse, mutect2, varscan2
- LILRA1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 132/460 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs150040624; called by muse, varscan2
- LILRA1 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 95/388 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs367952905; called by muse, mutect2, varscan2
- LILRA2 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 165/798 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs770183945, COSV52191773; called by muse, varscan2
- LMOD2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 144/472 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs371400622; called by muse, mutect2, varscan2
- LOXL2 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99743673; called by muse, mutect2, varscan2
- LRRC53 | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs186092838; called by mutect2, varscan2
- LRRC63 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1189295066; called by muse, mutect2, varscan2
- LRRC7 | c.329G>A p.R110Q (on ENST00000651989 / NM_001370785.2; = p.R77Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 206/274 reads (75%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs267598703, COSV50462590; called by muse, mutect2, varscan2
- LRRN2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 554/613 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141763834; called by muse, mutect2, varscan2
- LRRTM4 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 71/356 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV69139163; called by muse, mutect2, varscan2
- LTBP2 | c.4761G>A p.W1587* | Nonsense Mutation (SNP) | VAF 170/323 reads (53%) | catalogued as COSV56205787; called by muse, mutect2, varscan2
- LTBP2 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 143/482 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs751582703; called by muse, mutect2, varscan2
- MACC1 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 113/484 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV60540760; called by muse, mutect2, varscan2
- MAGEA10 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 284/369 reads (77%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.891); catalogued as rs766302328; called by muse, mutect2, varscan2
- MAGEC1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 277/389 reads (71%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.86); catalogued as COSV53579372; called by muse, mutect2, varscan2
- MAGI3 | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 281/400 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776665703, COSV100289112; called by muse, mutect2, varscan2
- MAMDC2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 268/314 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs368297806; called by muse, mutect2, varscan2
- MAP3K5 | c.3514C>T p.P1172S | Missense Mutation (SNP) | VAF 177/214 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62887558; called by muse, mutect2, varscan2
- MAPK3 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 234/277 reads (84%) | catalogued as COSV99531924; called by muse, mutect2, varscan2
- MARK1 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 434/469 reads (93%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs745932586, COSV100857307; called by muse, mutect2, varscan2
- MCCD1 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 240/676 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs772597720; called by muse, mutect2, varscan2
- MCMDC2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs772048792, COSV58037223; called by muse, mutect2, varscan2
- MCOLN1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 141/244 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51176800; called by muse, mutect2, varscan2
- MCTP1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 139/281 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs200443526; called by muse, mutect2, varscan2
- MCUR1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 112/345 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs767442278, COSV100848922; called by muse, mutect2, varscan2
- MED13 | c.3628C>T p.P1210S | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs759251419; called by muse, mutect2, varscan2
- MEGF10 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 132/281 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57249059; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 192/420 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, varscan2
- MGAM2 | c.5875G>A p.D1959N | Missense Mutation (SNP) | VAF 78/812 reads (10%) | SIFT tolerated, low confidence (0.75); catalogued as rs963233882; called by muse, mutect2
- MIA2 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs754149612, COSV54482945; called by muse, mutect2, varscan2
- MICAL2 | c.4418C>T p.S1473F | Missense Mutation (SNP) | VAF 191/330 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); catalogued as rs374774096; called by muse, mutect2, varscan2
- MINDY4 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 250/371 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs536283558; called by muse, mutect2, varscan2
- MKI67 | c.3812G>A p.R1271K | Missense Mutation (SNP) | VAF 236/294 reads (80%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.579); catalogued as rs765282623, COSV64075463; called by muse, mutect2, varscan2
- MN1 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 688/1049 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV56555852; called by muse, mutect2, varscan2
- MNX1 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 79/756 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.083); catalogued as rs992402696, COSV53318101, COSV99429836; called by muse, mutect2, varscan2
- MROH2B | c.3577G>A p.G1193R | Missense Mutation (SNP) | VAF 121/262 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV101270772; called by muse, mutect2, varscan2
- MROH6 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 283/588 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.386); catalogued as rs1051555447; called by muse, mutect2, varscan2
- MRPL38 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs371715586; called by muse, mutect2, varscan2
- MS4A1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210730619, COSV100619266, COSV61941897; called by muse, mutect2, varscan2
- MTIF2 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 73/442 reads (17%) | catalogued as rs781465997, COSV55053308; called by muse, mutect2, varscan2
- MTOR | c.4417G>T p.D1473Y | Missense Mutation (SNP) | VAF 111/614 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1313381757, COSV63868827, COSV63869329; called by muse, mutect2, varscan2
- MUC16 | c.37640C>T p.T12547I | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as rs545429785, COSV67447770; called by muse, mutect2, varscan2
- MUC16 | c.27068C>T p.P9023L | Missense Mutation (SNP) | VAF 181/416 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.023); catalogued as COSV67446839; called by muse, mutect2, varscan2
- MUC16 | c.17551C>T p.P5851S | Missense Mutation (SNP) | VAF 127/288 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs267605800, COSV67460962; called by muse, mutect2, varscan2
- MUC16 | c.17269G>A p.D5757N | Missense Mutation (SNP) | VAF 128/271 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.917); catalogued as rs910009324, COSV67477126; called by muse, mutect2, varscan2
- MUC16 | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 136/352 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs375187648, COSV101198066, COSV104432151; called by muse, varscan2
- MUC16 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 192/460 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs369271832; called by muse, mutect2, varscan2
- MUC16 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 171/366 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as COSV67442269; called by muse, mutect2, varscan2
- MUC17 | c.6091G>A p.G2031S | Missense Mutation (SNP) | VAF 202/293 reads (69%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.982); catalogued as rs1310896897; called by muse, mutect2, varscan2
- MUC17 | c.11198C>T p.S3733L | Missense Mutation (SNP) | VAF 60/466 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60296811; called by muse, mutect2, varscan2
- MUTYH | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs773108803, COSV58344939; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.4374C>T p.I1458= | Splice Region (SNP) | VAF 125/229 reads (55%) | catalogued as COSV55449541; called by muse, mutect2, varscan2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 161/380 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1259211052; called by muse, mutect2, varscan2
- MYO18B | c.7591C>T p.P2531S | Missense Mutation (SNP) | VAF 396/581 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV59149632; called by muse, varscan2
- MYO18B | c.7619G>A p.R2540Q | Missense Mutation (SNP) | VAF 128/516 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs749740047, COSV100123020; called by muse, varscan2
- MYO1H | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 275/322 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1425604047, COSV100183482, COSV99081637; called by muse, mutect2, varscan2
- NAALADL1 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 157/346 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371781219; called by muse, mutect2, varscan2
- NBAS | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 65/340 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1337326154; called by muse, mutect2, varscan2
- NBEA | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 226/397 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs267603808, COSV59766496, COSV59830102; called by muse, mutect2, varscan2
- NBEA | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 166/286 reads (58%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV59805786; called by muse, mutect2, varscan2
- NCOA6 | c.6176G>A p.R2059Q | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs1191558154, COSV62868558; called by muse, mutect2, varscan2
- NCR2 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 289/529 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753979828, COSV66100665; called by muse, mutect2, varscan2
- NDN | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 104/351 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs763474594, COSV59361197; called by muse, mutect2, varscan2
- NDUFA11 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs772849772; called by muse, mutect2, varscan2
- NEB | c.8026G>A p.E2676K | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1460283559; called by muse, mutect2, varscan2
- NEFM | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 200/502 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204258828; called by muse, mutect2, varscan2
- NELL1 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.852); catalogued as rs1312307752; called by muse, mutect2, varscan2
- NFKBIE | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 483/863 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV51487728; called by muse, varscan2
- NKD2 | c.201G>A p.Q67= | Splice Region (SNP) | VAF 152/416 reads (37%) | catalogued as COSV56890936; called by muse, mutect2, varscan2
- NLRP10 | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 241/447 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755155590, COSV60778802; called by muse, mutect2, varscan2
- NLRP14 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 101/188 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as rs867695793; called by muse, mutect2, varscan2
- NLRP3 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 457/494 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs104895414, CM071602, COSV60231611; ClinVar: not provided; called by muse, mutect2, varscan2
- NLRP4 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV56710757; called by muse, mutect2, varscan2
- NLRP5 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 92/266 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as rs1200452996, COSV66761780; called by muse, varscan2
- NOTCH3 | c.6878C>T p.P2293L | Missense Mutation (SNP) | VAF 195/469 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54630048; called by muse, mutect2, varscan2
- NOTCH3 | c.3074C>G p.P1025R | Missense Mutation (SNP) | VAF 192/461 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV54630897, COSV54634871; called by muse, mutect2, varscan2
- NRXN1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 119/583 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1489429289; called by muse, mutect2, varscan2
- NRXN2 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 127/265 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1265735218; called by muse, mutect2, varscan2
- NSUN7 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57276272; called by muse, mutect2
- NTM | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 123/178 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66177919; called by muse, mutect2, varscan2
- NTRK3 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 130/217 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1395756451, COSV62298363; called by muse, mutect2, varscan2
- NWD2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100519736; called by muse, mutect2, varscan2
- OBSCN | c.8900G>A p.G2967D | Missense Mutation (SNP) | VAF 632/690 reads (92%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as rs367712031; called by muse, varscan2
- OFD1 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 263/323 reads (81%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs748643730; called by muse, mutect2, varscan2
- OLFM2 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 163/353 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.158); catalogued as rs756244167; called by muse, mutect2, varscan2
- OR10A3 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 116/382 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs866622532, COSV62459092; called by muse, mutect2, varscan2
- OR10C1 | c.38T>G p.F13C (on ENST00000622521; = p.F11C on NM_013941.3) | Missense Mutation (SNP) | VAF 306/927 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65822494; called by muse, mutect2, varscan2
- OR12D3 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 370/1010 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1298594837; called by muse, mutect2, varscan2
- OR1N1 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 267/298 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs778357078, COSV59197039; called by muse, mutect2, varscan2
- OR1Q1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 357/405 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52917616; called by muse, mutect2, varscan2
- OR2A12 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 49/560 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1437273108; called by muse, mutect2
- OR2A2 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 70/483 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV68872634; called by muse, varscan2
- OR2A25 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs781251490, COSV68716866, COSV68716922; called by muse, mutect2
- OR2A25 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as COSV68717029; called by muse, mutect2
- OR2D2 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV55057547; called by muse, mutect2, varscan2
- OR2T2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 684/1457 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760149658, COSV61617769; called by muse, mutect2, varscan2
- OR4B1 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 145/348 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58882054; called by muse, mutect2, varscan2
- OR4C5 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 133/361 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); catalogued as rs918149366, COSV60563452; called by muse, mutect2, varscan2
- OR4E1 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs546907185; called by muse, mutect2, varscan2
- OR4K13 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1566530921, COSV59860862; called by muse, mutect2, varscan2
- OR4K15 | c.701C>T p.S234F (on ENST00000305051; = p.S210F on NM_001005486.1) | Missense Mutation (SNP) | VAF 158/268 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV59300274; called by muse, mutect2, varscan2
- OR4K17 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as rs1311596870, COSV100210616; called by muse, mutect2, varscan2
- OR4N2 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 122/410 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV60054844; called by muse, mutect2, varscan2
- OR4Q3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177294; called by muse, mutect2, varscan2
- OR4X1 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 182/460 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs754663946, COSV60724281; called by muse, mutect2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 122/245 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, mutect2, varscan2
- OR52A1 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV61093038; called by muse, mutect2, varscan2
- OR52K2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 179/329 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs766771557; called by muse, mutect2, varscan2
- OR52R1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 145/233 reads (62%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as rs370070710, COSV61887659; called by muse, mutect2, varscan2
- OR56A4 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 171/289 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1360583886; called by muse, mutect2, varscan2
- OR56B1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV57723733; called by muse, mutect2, varscan2
- OR5A1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 158/396 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574597111, COSV57375852; called by muse, mutect2, varscan2
- OR5AP2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 140/317 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV57257668; called by muse, varscan2
- OR8D2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 114/150 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100659130, COSV62488279; called by muse, mutect2, varscan2
- OSBPL7 | c.810T>G p.H270Q | Missense Mutation (SNP) | VAF 192/272 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV50106980; called by muse, mutect2, varscan2
- OTOG | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 112/218 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1447677589; called by muse, mutect2, varscan2
- OXCT2 | c.1529G>A p.R510K | Missense Mutation (SNP) | VAF 138/563 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765862292; called by muse, mutect2
- P2RX4 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 247/290 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs750261530; called by muse, mutect2, varscan2
- PAK5 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 251/471 reads (53%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.888); catalogued as rs1262495622, COSV62022080; called by muse, mutect2, varscan2
- PAPPA | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 353/405 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60286958; called by muse, mutect2, varscan2
- PAPPA2 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 479/529 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV62773428; called by muse, mutect2, varscan2
- PAPPA2 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 318/351 reads (91%) | SIFT tolerated (0.18); PolyPhen benign (0.233); catalogued as rs191519115; called by muse, mutect2, varscan2
- PARP16 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 186/347 reads (54%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99975407; called by muse, mutect2, varscan2
- PASK | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 247/384 reads (64%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV52148063; called by muse, mutect2, varscan2
- PAX8 | c.192G>C p.R64S | Missense Mutation (SNP) | VAF 150/235 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54507484; called by muse, mutect2, varscan2
- PCARE | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 239/406 reads (59%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as COSV59053684, COSV59058707; called by muse, mutect2, varscan2
- PCDH17 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 230/378 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100931783, COSV64973397; called by muse, mutect2, varscan2
- PCDH18 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 39/484 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.124); catalogued as rs374589170; called by muse, mutect2
- PCDHA3 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 127/306 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as rs1554122639; called by muse, mutect2, varscan2
- PCDHB11 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 238/1078 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.234); catalogued as rs1554285622; called by muse, varscan2
- PCDHB12 | c.1381C>A p.R461S | Missense Mutation (SNP) | VAF 332/765 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs782479486; called by muse, mutect2, varscan2
- PCDHB4 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 351/767 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs146284769; called by muse, mutect2, varscan2
- PCDHGA2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 165/370 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.139); catalogued as COSV53925127; called by muse, mutect2, varscan2
- PCDHGA9 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 173/403 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs377389968; called by muse, mutect2, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 152/399 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2, varscan2
- PCK2 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV53751092; called by mutect2, varscan2
- PCLO | c.7262C>T p.P2421L | Missense Mutation (SNP) | VAF 108/141 reads (77%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1196374147; called by muse, mutect2, varscan2
- PCLO | c.6454G>A p.E2152K | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV61636627; called by muse, mutect2
- PCLO | c.5621C>T p.P1874L | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs371631647, COSV61631945; called by muse, mutect2, varscan2
- PCLO | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 286/394 reads (73%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.085); catalogued as COSV61620963; called by muse, mutect2, varscan2
- PCNT | c.8562A>C p.K2854N | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.421); catalogued as COSV100855449; called by muse, mutect2, varscan2
- PCSK1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1439220661; called by muse, mutect2, varscan2
- PCSK6 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 120/205 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323235197, COSV59342913; called by muse, mutect2, varscan2
- PDE11A | c.1909G>A p.V637I | Missense Mutation (SNP) | VAF 220/337 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0.207); catalogued as rs539536729, COSV53706005; called by muse, mutect2, varscan2
- PDE4DIP | c.5649G>A p.R1883= | Splice Region (SNP) | VAF 278/307 reads (91%) | catalogued as rs1282280555, COSV57711888; called by muse, mutect2, varscan2
- PEAK1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs763796402; called by muse, mutect2, varscan2
- PFKFB1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 194/237 reads (82%) | PolyPhen benign (0.054); catalogued as rs150213595, COSV66628924; called by muse, mutect2, varscan2
- PGK2 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 470/890 reads (53%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.98); catalogued as COSV59164877; called by muse, mutect2, varscan2
- PIEZO2 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 220/264 reads (83%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs1486015917; called by muse, varscan2
- PIK3C2G | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 183/240 reads (76%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV56819107; called by muse, mutect2, varscan2
- PIMREG | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.301); catalogued as rs1254336242; called by muse, mutect2, varscan2
- PKD2L1 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 342/391 reads (87%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs147259519; called by muse, mutect2, varscan2
- PKDREJ | c.6434G>A p.R2145K | Missense Mutation (SNP) | VAF 107/463 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as COSV99478526; called by muse, mutect2, varscan2
- PKHD1 | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 235/624 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM149115, COSV100581071, COSV61882957; called by muse, mutect2, varscan2
- PKHD1 | c.1576A>G p.I526V | Missense Mutation (SNP) | VAF 90/627 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs142608481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1L1 | c.4301G>A p.G1434E | Missense Mutation (SNP) | VAF 136/333 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1185554521, COSV65738242, COSV65742422; called by muse, mutect2, varscan2
- PKHD1L1 | c.8437C>G p.P2813A | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV65743098; called by muse, mutect2, varscan2
- PLCH1 | c.4007C>T p.S1336F (on ENST00000340059 / NM_001130960.2; = p.S1328F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 317/374 reads (85%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.317); catalogued as COSV100397973; called by muse, mutect2, varscan2
- PLEKHA7 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201494675, COSV63046349; called by muse, mutect2, varscan2
- PLXDC2 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 172/203 reads (85%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs1416218731; called by muse, mutect2, varscan2
- PLXNA4 | c.2687T>C p.V896A | Missense Mutation (SNP) | VAF 315/659 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58126734; called by muse, mutect2, varscan2
- PLXNB1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 423/615 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761471990; called by muse, mutect2, varscan2
- PNLIP | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 186/223 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866345576, COSV100981593, COSV65040597, COSV65041391; called by muse, mutect2, varscan2
- POLA2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 151/347 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs1436036700; called by muse, mutect2, varscan2
- POLI | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 143/173 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs369815747, COSV99471159; called by muse, mutect2, varscan2
- POM121L12 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 345/630 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.267); catalogued as rs746047304, COSV68692144; called by muse, mutect2, varscan2
- POTEE | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 30/329 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV100387802, COSV58230646; called by muse, mutect2
- POTEG | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 111/1100 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1190367003; called by muse, mutect2, varscan2
- POU3F3 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 350/554 reads (63%) | catalogued as COSV63721611; called by muse, mutect2
- PPFIA1 | c.3218T>C p.I1073T | Missense Mutation (SNP) | VAF 265/493 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs149188477; called by muse, mutect2, varscan2
- PPFIA2 | c.3057G>A p.M1019I | Missense Mutation (SNP) | VAF 206/252 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100335233; called by muse, mutect2, varscan2
- PPFIA2 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 178/213 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1449867428; called by muse, mutect2, varscan2
- PPP1R2B | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 150/471 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV70372837; called by muse, mutect2, varscan2
- PPP1R3A | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 200/275 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs1275417952, COSV52879106, COSV52880839; called by muse, mutect2, varscan2
- PPP4R4 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 193/320 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1261351555; called by muse, mutect2, varscan2
- PRAMEF1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 40/393 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV60007495; called by muse, mutect2, varscan2
- PRAMEF11 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 115/823 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.187); catalogued as rs773211732, COSV101463306; called by muse, mutect2, varscan2
- PRAMEF12 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 138/201 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs752095583, COSV63215039; called by muse, mutect2, varscan2
- PRAMEF2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 117/650 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs1063791; called by muse, mutect2, varscan2
- PRB2 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 303/420 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV66982042; called by muse, mutect2, varscan2
- PRDM9 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV57013336, COSV99690363; called by muse, mutect2, varscan2
- PREX1 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 189/349 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs780759564; called by muse, mutect2, varscan2
- PRKAA2 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 362/407 reads (89%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64801684; called by muse, mutect2, varscan2
- PRKG2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 229/287 reads (80%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867660938, COSV52320273; called by muse, mutect2, varscan2
- PRR30 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 285/469 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.368); catalogued as rs1271614694; called by muse, mutect2, varscan2
- PRSS57 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 199/389 reads (51%) | SIFT tolerated (0.72); PolyPhen benign (0.102); catalogued as rs575963662; called by muse, mutect2, varscan2
- PRUNE2 | c.6974C>T p.S2325F | Missense Mutation (SNP) | VAF 268/295 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV65042576; called by muse, mutect2, varscan2
- PRUNE2 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 182/212 reads (86%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV65029878; called by muse, mutect2, varscan2
- PSG2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 217/375 reads (58%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs376432612; called by muse, mutect2, varscan2
- PSMD5 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 458/495 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52960217; called by muse, mutect2, varscan2
- PSMG1 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 121/154 reads (79%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV59001460; called by muse, mutect2, varscan2
- PTPN4 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 131/208 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1186373089, COSV55298093, COSV99750484; called by muse, mutect2, varscan2
- PTPN9 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV100144445; called by muse, mutect2, varscan2
- PTPRC | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 413/459 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs748511747, COSV61409994; called by muse, mutect2, varscan2
- PTPRD | c.4506+1G>A p.X1502_splice | Splice Site (SNP) | VAF 211/233 reads (91%) | catalogued as rs1356752980; called by muse, mutect2, varscan2
- PTPRH | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 53/257 reads (21%) | catalogued as rs142263222; called by muse, mutect2, varscan2
- PTPRS | c.5318C>T p.S1773L | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779302415, COSV53619781; called by muse, mutect2, varscan2
- PTPRT | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 237/448 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV62013512; called by muse, mutect2, varscan2
- RAG1 | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 214/423 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs866862677, COSV55025161; called by muse, mutect2, varscan2
- RASAL1 | c.732G>A p.G244= | Splice Region (SNP) | VAF 151/175 reads (86%) | catalogued as rs145345802; called by muse, mutect2, varscan2
- RASGEF1C | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 160/360 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774080726; called by muse, mutect2, varscan2
- RBM23 | c.358C>T p.R120C (on ENST00000359890 / NM_001077351.2; = p.R104C on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/318 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs761437876, COSV57127804; called by muse, varscan2
- RELN | c.1813C>T p.H605Y | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.885); catalogued as rs762608682, COSV59002828; called by muse, mutect2, varscan2
- RLF | c.4609C>T p.L1537F | Missense Mutation (SNP) | VAF 57/468 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.661); catalogued as COSV65653340; called by muse, mutect2, varscan2
- RNF133 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 166/524 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as rs776077003, COSV100411404, COSV57387212; called by muse, varscan2
- RP1 | c.1704G>A p.W568* | Nonsense Mutation (SNP) | VAF 97/205 reads (47%) | catalogued as COSV101587851, COSV73138824; called by muse, mutect2, varscan2
- RPS6KA4 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 225/556 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244409522; called by muse, mutect2, varscan2
- RSPH14 | c.792G>A p.G264= | Splice Region (SNP) | VAF 377/583 reads (65%) | catalogued as COSV53267250; called by muse, mutect2, varscan2
- RYR1 | c.6185G>A p.R2062H | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs368235923; called by muse, mutect2, varscan2
- SAFB | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as COSV52652238; called by muse, mutect2, varscan2
- SALL1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 305/357 reads (85%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.824); catalogued as COSV51761770; called by muse, mutect2, varscan2
- SART1 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 206/426 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56713479; called by muse, mutect2, varscan2
- SBF2 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs770723203, COSV56302182; called by muse, mutect2, varscan2
- SCN3A | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 237/364 reads (65%) | catalogued as COSV51820116; called by muse, mutect2, varscan2
- SCUBE2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1244271281, CM124525; called by muse, mutect2, varscan2
- SDK2 | c.4642G>A p.G1548R | Missense Mutation (SNP) | VAF 99/402 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV66187267; called by muse, mutect2, varscan2
- SERPINA1 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 179/735 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs551595739; called by muse, mutect2, varscan2
- SERPINB10 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 112/135 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539628633; called by muse, mutect2, varscan2
- SEZ6L | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 459/645 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99962780; called by muse, mutect2, varscan2
- SF3B1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 163/261 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV59211931, COSV59212622; called by muse, mutect2, varscan2
- SFMBT1 | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs745423147; called by muse, mutect2, varscan2
- SGSM1 | c.2587G>A p.E863K (on ENST00000400359 / NM_001039948.4; = p.E802K on NM_133454.3) | Missense Mutation (SNP) | VAF 453/679 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs764241355; called by muse, mutect2, varscan2
- SH3RF2 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 180/441 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV63041224; called by muse, mutect2, varscan2
- SHANK1 | c.5534G>A p.G1845D | Missense Mutation (SNP) | VAF 75/431 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.483); catalogued as rs1482432260; called by muse, mutect2, varscan2
- SHANK1 | c.4196C>T p.A1399V | Missense Mutation (SNP) | VAF 110/460 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1280923316; called by muse, varscan2
- SIRPB1 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 124/442 reads (28%) | catalogued as rs148690008; called by muse, mutect2
- SIRPB1 | c.435C>T p.A145= | Splice Region (SNP) | VAF 109/333 reads (33%) | catalogued as rs1246171795, COSV53541523; called by muse, mutect2, varscan2
- SIX2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 343/513 reads (67%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.093); catalogued as rs766312512; called by muse, mutect2, varscan2
- SKOR2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 223/261 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs1226917240; called by muse, mutect2, varscan2
- SLC12A8 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 294/335 reads (88%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs918768903; called by muse, mutect2, varscan2
- SLC13A5 | c.1299G>A p.M433I | Missense Mutation (SNP) | VAF 139/296 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV53425596; called by muse, mutect2, varscan2
- SLC17A3 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 406/705 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); catalogued as rs377515468; called by muse, varscan2
- SLC17A6 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 74/342 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs138159912, COSV54138373; called by muse, mutect2, varscan2
- SLC18A3 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 228/1002 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as rs761770195; called by muse, mutect2, varscan2
- SLC22A10 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 139/298 reads (47%) | catalogued as COSV60420873, COSV60421142; called by muse, varscan2
- SLC25A51 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 381/436 reads (87%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as rs1426256604; called by muse, mutect2, varscan2
- SLC27A6 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 107/256 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867556415, COSV99064213; called by muse, mutect2, varscan2
- SLC39A12 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 142/162 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV66194567, COSV66195394; called by muse, mutect2, varscan2
- SLC4A10 | c.2048G>A p.W683* (on ENST00000446997 / NM_001354461.2; = p.W653* on NM_022058.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 66/291 reads (23%) | catalogued as COSV55791768; called by muse, mutect2, varscan2
- SLC4A3 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 173/271 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1052409928; called by muse, mutect2, varscan2
- SLC6A11 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 72/407 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1559551814; called by muse, mutect2, varscan2
- SLC6A18 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 208/509 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219905024, COSV57250514; called by muse, mutect2, varscan2
- SLC8A1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 289/424 reads (68%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs763896494; called by muse, mutect2, varscan2
- SLC8B1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 252/289 reads (87%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV52526571; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1969G>A p.D657N (on ENST00000540229 / NM_001371097.1; = p.D596N on NM_001009562.4) | Missense Mutation (SNP) | VAF 87/109 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67441947; called by muse, mutect2, varscan2
- SLITRK6 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 167/261 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs1243884063, COSV68389758, COSV68391125; called by muse, mutect2, varscan2
- SMYD1 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 313/499 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs866274358, COSV70226047; called by muse, mutect2, varscan2
- SNCAIP | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 171/367 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775708743, COSV54420188; called by muse, mutect2, varscan2
- SNTG1 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV52427270; called by muse, mutect2, varscan2
- SNTG2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV58009297; called by muse, mutect2, varscan2
- SORL1 | c.759-1G>A p.X253_splice | Splice Site (SNP) | VAF 102/128 reads (80%) | catalogued as rs1377408732; called by muse, mutect2, varscan2
- SOWAHA | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 184/453 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1475147659; called by muse, mutect2, varscan2
- SPAG1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs928977296; called by muse, mutect2, varscan2
- SPAG17 | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 194/282 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1201454411, COSV60461015; called by muse, mutect2, varscan2
- SPANXN5 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 194/244 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV64968884; called by muse, mutect2, varscan2
- SPATS2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 191/239 reads (80%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as COSV58923434; called by muse, mutect2, varscan2
- SPDYE4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.865); catalogued as rs748791171, COSV100171295, COSV100171308; called by muse, mutect2, varscan2
- SPEG | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 129/539 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs1170905232, COSV56665041; called by muse, mutect2, varscan2
- SPEG | c.8470C>T p.P2824S | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56662195; called by muse, mutect2, varscan2
- SPHKAP | c.3686G>A p.R1229Q | Missense Mutation (SNP) | VAF 281/441 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754167845, COSV60871584; called by muse, mutect2, varscan2
- SPINT1 | c.1342G>A p.D448N (on ENST00000344051 / NM_181642.3; = p.D432N on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/214 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1418820560; called by muse, mutect2, varscan2
- SPRR2A | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 590/688 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV66991481; called by muse, mutect2, varscan2
- SPRR3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 557/594 reads (94%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); catalogued as rs867801692, COSV54878625; called by muse, mutect2, varscan2
- SPRYD7 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 125/221 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1190456570; called by muse, mutect2, varscan2
- SPTA1 | c.3668G>A p.R1223Q | Missense Mutation (SNP) | VAF 512/565 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148714399, COSV63754963; called by muse, mutect2, varscan2
- SRGAP3 | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 80/493 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1487155993; called by muse, mutect2, varscan2
- SRRM2 | c.7204C>T p.L2402F | Missense Mutation (SNP) | VAF 399/459 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs754776293; called by muse, mutect2, varscan2
- SSTR3 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 562/860 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100142881; called by muse, varscan2
- ST14 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 232/287 reads (81%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs760337264; called by muse, varscan2
- ST18 | c.1089G>C p.K363N | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV99389435; called by muse, mutect2, varscan2
- STARD9 | c.3767C>T p.P1256L | Missense Mutation (SNP) | VAF 158/316 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as rs1052615840; called by muse, mutect2, varscan2
- STAT5B | c.2155G>A p.G719R | Missense Mutation (SNP) | VAF 153/262 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs1269922038, COSV53184270, COSV53185067, COSV99510639; called by muse, mutect2, varscan2
- STEAP4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 177/272 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV57328130, COSV57331236; called by muse, mutect2, varscan2
- STK31 | c.2956G>A p.D986N | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV63456069; called by muse, mutect2, varscan2
- STON1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 102/468 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59139597; called by muse, mutect2, varscan2
- STXBP5L | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 97/123 reads (79%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV56525292; called by muse, mutect2, varscan2
- SULT1B1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 202/269 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV60208278; called by muse, mutect2, varscan2
- SUPT20H | c.890C>T p.P297L (on ENST00000350612 / NM_001014286.3; = p.P298L on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs200732187; called by muse, mutect2, varscan2
- SYBU | c.1988C>T p.T663I (on ENST00000276646 / NM_001099754.2; = p.T662I on NM_017786.6) | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs774840003; called by muse, mutect2, varscan2
- SYDE1 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 133/339 reads (39%) | catalogued as rs1237432733; called by muse, mutect2, varscan2
- SYMPK | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 116/227 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs943389564; called by muse, mutect2, varscan2
- SYN2 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 102/599 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as CM140009, COSV70286087; called by muse, mutect2, varscan2
- SYNJ2BP | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 109/194 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as rs772822266, COSV56445891; called by muse, mutect2, varscan2
- SYT10 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 122/148 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99952205; called by muse, mutect2, varscan2
- SYT12 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 249/522 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as COSV67355519; called by muse, mutect2, varscan2
- SYT16 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 136/257 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374283682, COSV101413525; called by muse, mutect2, varscan2
- SYT3 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs866261528, COSV58899319; called by muse, mutect2, varscan2
- TAF6 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 268/372 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59844086; called by muse, mutect2, varscan2
- TAS2R60 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 54/460 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767812355, COSV60330541; called by muse, varscan2
- TBC1D5 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV53751126; called by muse, mutect2, varscan2
- TBXT | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 356/421 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs753100833, COSV51616429; called by muse, mutect2, varscan2
- TCHHL1 | c.2135G>A p.R712K | Missense Mutation (SNP) | VAF 378/402 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs1184509503, COSV64287046; called by muse, mutect2, varscan2
- TENM2 | c.3655C>T p.R1219C (on ENST00000518659 / NM_001122679.2; = p.R987C on NM_001080428.3) | Missense Mutation (SNP) | VAF 187/485 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371063467; called by muse, mutect2, varscan2
- TENM4 | c.6652G>A p.D2218N | Missense Mutation (SNP) | VAF 209/466 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764096276, COSV53611389; called by muse, varscan2
- TENM4 | c.3241C>T p.H1081Y | Missense Mutation (SNP) | VAF 209/493 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs1234905744; called by muse, mutect2, varscan2
- TENT5D | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 246/290 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57638844; called by muse, mutect2, varscan2
- THEG | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1378700394, COSV100700587; called by muse, mutect2, varscan2
- THSD7B | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 78/353 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs754916507, COSV55714925; called by muse, mutect2, varscan2
- TINAG | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 320/708 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV52510057, COSV99448496; called by muse, mutect2, varscan2
- TLL1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 336/431 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV50281947; called by muse, varscan2
- TLR8 | c.1694C>T p.S565L (on ENST00000218032 / NM_138636.5; = p.S583L on NM_016610.4) | Missense Mutation (SNP) | VAF 126/154 reads (82%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV54316657; called by muse, mutect2, varscan2
- TMC2 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 206/410 reads (50%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs141505256; called by muse, mutect2, varscan2
- TMEM63C | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs577654792; called by muse, mutect2, varscan2
- TMPRSS15 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 209/260 reads (80%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1338875221; called by muse, mutect2, varscan2
- TMPRSS7 | c.592G>A p.A198T (on ENST00000452346; = p.A85T on NM_001042575.2) | Missense Mutation (SNP) | VAF 294/350 reads (84%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs866247414; called by muse, mutect2, varscan2
- TNXB | c.2389C>T p.R797W | Missense Mutation (SNP) | VAF 315/600 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs563472994, COSV64479134; called by muse, mutect2, varscan2
- TOMM7 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100626941; called by muse, mutect2
- TPH1 | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV51457280; called by muse, mutect2, varscan2
- TPH2 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 275/338 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as rs773096016, COSV61591462, COSV61593532, COSV61594165; called by muse, mutect2, varscan2
- TPST2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 480/719 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV58679171; called by muse, mutect2, varscan2
- TPTE | c.569G>A p.W190* (on ENST00000618007 / NM_199261.4; = p.W172* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as rs1255334410; called by muse, mutect2, varscan2
- TRAV6 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs1213744651; called by muse, mutect2, varscan2
- TRHR | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.045); catalogued as COSV61233422; called by muse, mutect2, varscan2
- TRIM35 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 131/327 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369310263; called by muse, varscan2
- TRIOBP | c.4159C>T p.R1387W | Missense Mutation (SNP) | VAF 464/705 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs370108541; called by muse, mutect2, varscan2
- TRPC3 | c.652G>A p.D218N (on ENST00000379645 / NM_001366479.2; = p.D145N on NM_003305.2) | Missense Mutation (SNP) | VAF 46/536 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1348793380, COSV53379102; called by muse, mutect2
- TRPM5 | c.1817G>A p.W606* | Nonsense Mutation (SNP) | VAF 103/397 reads (26%) | catalogued as rs1440522343; called by muse, mutect2, varscan2
- TRPM6 | c.3890G>A p.R1297K | Missense Mutation (SNP) | VAF 319/360 reads (89%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1440851175, COSV62507013, COSV62510751; called by muse, mutect2, varscan2
- TRPM8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 131/247 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs919281308, COSV100224345; called by muse, mutect2, varscan2
- TSHB | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 110/655 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs199873661; called by muse, mutect2, varscan2
- TSPEAR | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 227/281 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs782375762; called by muse, mutect2, varscan2
- TSPOAP1 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 128/502 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52104641; called by muse, mutect2, varscan2
- TSSK1B | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 134/368 reads (36%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as rs374467859; called by muse, varscan2
- TSSK3 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 75/550 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs770319759, COSV100344936, COSV61982706; called by muse, mutect2, varscan2
- TTBK1 | c.3229G>A p.E1077K | Missense Mutation (SNP) | VAF 298/861 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV99444230; called by muse, mutect2, varscan2
- TTBK1 | c.3493C>T p.P1165S | Missense Mutation (SNP) | VAF 329/934 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1158098886; called by muse, mutect2
- TTN | c.73808A>G p.N24603S (on ENST00000591111; = p.N17179S on NM_003319.4) | Missense Mutation (SNP) | VAF 202/339 reads (60%) | PolyPhen benign (0.164); catalogued as COSV100588455; called by muse, mutect2, varscan2
- TTN | c.53189C>T p.S17730L (on ENST00000591111; = p.S10306L on NM_003319.4) | Missense Mutation (SNP) | VAF 81/403 reads (20%) | PolyPhen probably damaging (0.996); catalogued as COSV60386013; called by muse, mutect2, varscan2
- TTN | c.48730G>A p.E16244K (on ENST00000591111; = p.E8820K on NM_003319.4) | Missense Mutation (SNP) | VAF 211/346 reads (61%) | PolyPhen benign (0.036); catalogued as CM1413537; called by muse, mutect2, varscan2
- TTN | c.38746G>A p.D12916N (on ENST00000591111; = p.D5492N on NM_003319.4) | Missense Mutation (SNP) | VAF 89/550 reads (16%) | PolyPhen benign (0.003); catalogued as rs794729431, COSV60181732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.28907G>A p.G9636D (on ENST00000591111; = p.G8709D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 283/434 reads (65%) | PolyPhen probably damaging (0.959); catalogued as rs1201726118; called by muse, mutect2, varscan2
- TTN | c.20962G>A p.E6988K (on ENST00000591111; = p.E6061K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 285/479 reads (59%) | PolyPhen benign (0.099); catalogued as rs867359588, COSV60255234; called by muse, mutect2, varscan2
- TTN | c.18071C>T p.S6024L (on ENST00000591111; = p.S5097L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/425 reads (21%) | PolyPhen benign (0.306); catalogued as rs868170582, COSV59965477, COSV60280617; called by muse, mutect2, varscan2
- TTN | c.6322G>A p.E2108K (on ENST00000591111; = p.E2062K on NM_003319.4) | Missense Mutation (SNP) | VAF 104/467 reads (22%) | PolyPhen probably damaging (0.994); catalogued as rs762999586, COSV60013101; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- TUBA3C | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 130/523 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV67139954; called by muse, mutect2, varscan2
- TUFM | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 218/265 reads (82%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV57949647; called by muse, mutect2, varscan2
- TYK2 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53385795; called by muse, mutect2, varscan2
- UBQLN3 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs756923573; called by muse, mutect2, varscan2
- UGT1A4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 293/428 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV100529910; called by muse, mutect2, varscan2
- UGT2B17 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 147/189 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV58501062; called by muse, mutect2, varscan2
- UMODL1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 180/221 reads (81%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as COSV68558172; called by muse, mutect2, varscan2
- UNC13C | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 135/280 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); catalogued as rs1425768653; called by muse, mutect2, varscan2
- UNC13C | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52923813; called by muse, mutect2, varscan2
- UNC13C | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs768039530, COSV52841291, COSV52849785; called by muse, mutect2, varscan2
- UNC5B | c.1773C>T p.L591= | Splice Region (SNP) | VAF 129/158 reads (82%) | catalogued as COSV58974670; called by muse, mutect2, varscan2
- UNC5C | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146344947; called by muse, mutect2, varscan2
- UNC79 | c.2525C>T p.P842L (on ENST00000393151 / NM_001346218.2; = p.P665L on NM_020818.5) | Missense Mutation (SNP) | VAF 213/440 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs760074934, COSV56372105; called by muse, mutect2, varscan2
- UNC93B1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 196/486 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.343); catalogued as COSV99916326; called by muse, mutect2, varscan2
- USP26 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 205/253 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as rs748525921, COSV100896537; called by muse, varscan2
- USP29 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954305714, COSV54143387; called by muse, mutect2, varscan2
- USP36 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 250/402 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs549596089; called by muse, mutect2, varscan2
- VAV1 | c.207C>T p.F69= | Splice Region (SNP) | VAF 37/151 reads (25%) | catalogued as rs780489736; called by muse, mutect2, varscan2
- VN1R2 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV59038143; called by muse, varscan2
- VPS13B | c.10928C>T p.A3643V | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100661029, COSV62142496; called by muse, mutect2, varscan2
- VPS13C | c.1706G>A p.G569E (on ENST00000644861 / NM_020821.3; = p.G526E on NM_017684.5) | Missense Mutation (SNP) | VAF 128/227 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51164954; called by muse, mutect2, varscan2
- VWA3B | c.2495G>A p.G832E | Missense Mutation (SNP) | VAF 140/224 reads (63%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs779891369; called by muse, varscan2
- VWA5B2 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 270/337 reads (80%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs745339755, COSV56610795, COSV56613561; called by muse, mutect2, varscan2
- VWC2L | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 76/411 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56980813; called by muse, mutect2, varscan2
- WDFY4 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 167/859 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs148176877, COSV57427113; called by muse, mutect2, varscan2
- WDFY4 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 574/847 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747294517; called by muse, mutect2, varscan2
- WDR17 | c.3088C>T p.P1030S | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs148885558; called by muse, mutect2, varscan2
- WDR17 | c.3890C>T p.S1297F | Missense Mutation (SNP) | VAF 357/426 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54581765; called by muse, mutect2, varscan2
- WDR19 | c.3430C>T p.P1144S | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as rs780714075; called by muse, mutect2
- WDR87 | c.7090G>A p.E2364K | Missense Mutation (SNP) | VAF 83/338 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as rs1327970043, COSV58202457; called by muse, mutect2, varscan2
- WDR87 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 134/250 reads (54%) | catalogued as rs975234445; called by muse, mutect2, varscan2
- WDR93 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 197/373 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as rs749743648; called by muse, mutect2, varscan2
- WRN | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs761819112, COSV53298883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WRNIP1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 463/1192 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1047032263; called by muse, mutect2, varscan2
- WWC1 | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 133/316 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368175149; called by muse, varscan2
- XDH | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.627); catalogued as rs763648123, COSV65150178; called by muse, varscan2
- XIRP2 | c.1905G>A p.W635* (on ENST00000628543; = p.W810* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 267/388 reads (69%) | catalogued as rs1285230507; called by muse, mutect2, varscan2
- XKR5 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199717191; called by muse, mutect2, varscan2
- ZBTB47 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 446/616 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs951511200; called by muse, varscan2
- ZC3H3 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 285/579 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs778193896; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 231/498 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868038766; called by muse, mutect2, varscan2
- ZFHX4 | c.6025C>T p.P2009S | Missense Mutation (SNP) | VAF 268/519 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99259321; called by muse, varscan2
- ZFP92 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 176/212 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV58599140; called by muse, mutect2, varscan2
- ZMAT4 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 172/366 reads (47%) | catalogued as COSV52691798, COSV52710566; called by muse, mutect2, varscan2
- ZMYM2 | c.3472C>T p.R1158* | Nonsense Mutation (SNP) | VAF 50/357 reads (14%) | catalogued as COSV67033372; called by muse, mutect2, varscan2
- ZNF177 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 186/458 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs758925650; called by muse, mutect2, varscan2
- ZNF18 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 207/474 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1304184948, COSV59552405; called by muse, mutect2, varscan2
- ZNF260 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 179/306 reads (58%) | catalogued as rs182026084; called by muse, mutect2, varscan2
- ZNF281 | c.2312C>T p.S771F | Missense Mutation (SNP) | VAF 421/474 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV54166142; called by muse, mutect2, varscan2
- ZNF285 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV58408412; called by muse, mutect2, varscan2
- ZNF335 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 211/372 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780577772, COSV59817450; called by muse, mutect2, varscan2
- ZNF385D | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 87/484 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs141254644; called by muse, mutect2, varscan2
- ZNF445 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 247/330 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68539273; called by muse, mutect2, varscan2
- ZNF501 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 342/467 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV68516136; called by muse, mutect2, varscan2
- ZNF528 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 78/375 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100846682; called by muse, mutect2, varscan2
- ZNF574 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 161/296 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV99726486; called by muse, mutect2, varscan2
- ZNF578 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 213/324 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV69737524; called by muse, mutect2, varscan2
- ZNF594 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs779743392; called by muse, mutect2, varscan2
- ZNF665 | c.325C>T p.R109* (on ENST00000600412; = p.R174* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/311 reads (19%) | catalogued as rs1042133945; called by muse, mutect2, varscan2
- ZNF676 | c.1124G>A p.G375E (on ENST00000650058; = p.G343E on NM_001001411.3) | Missense Mutation (SNP) | VAF 221/647 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101236211, COSV68094205, COSV68095102; called by muse, mutect2, varscan2
- ZNF699 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 195/456 reads (43%) | catalogued as rs145027997, COSV58026240; called by muse, mutect2, varscan2
- ZNF699 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 187/389 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100426862; called by muse, mutect2, varscan2
- ZNF737 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as rs782305873, COSV101417654; called by muse, mutect2, varscan2
- ZNF793 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 181/311 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs749691796, COSV101495686; called by muse, mutect2, varscan2
- ZNF836 | c.1889G>T p.R630I | Missense Mutation (SNP) | VAF 87/414 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs774948714, COSV100440501, COSV59080964; called by muse, mutect2, varscan2
1,479 further variants in this file (672 protein-altering or splice-affecting, 708 silent, 99 other) are not listed here.
